Gene-level copy-number profile of tumor specimen HTMCP-03-06-02150-01A from CGCI case HTMCP-03-06-02150, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 28.7 years (10,480 days).
Specimen HTMCP-03-06-02150-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c1ebbfa8-7bdb-46a4-9162-1fecb6a9cbc8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02150-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/5d08adaf-2508-46cf-bc04-65d0b23e8380

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,716; copy number 2: 42,887; copy number 3: 9,267; copy number 4: 3,459; copy number 5: 237; copy number 6: 1; copy number 7: 6; copy number 8: 723; copy number 9: 12; copy number 10: 6; copy number 11: 1; copy number 12: 10; copy number 16: 1; copy number 24: 4; copy number 31: 10; copy number 38: 6; copy number 41: 30; copy number 44: 6; copy number 77: 11.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,064 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,801,747–16,105,841, 11 genes, copy number 77: AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1.
- chr4:68,182,292–68,212,470, 1 gene, copy number 5 (within-gene range 3–5): FTLP10.
- chr7:38,269,491–38,300,322, 6 genes, copy number 7 (within-gene range 4–7): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr9:6,215,786–6,257,983, 1 gene, copy number 5: IL33.
- chr12:12,310–17,167,790, 540 genes, copy number 5–8 (broad region; genes not listed).
- chr12:17,710,934–17,711,046, 1 gene, copy number 5: Y_RNA.
- chr12:21,501,781–34,249,958, 246 genes, copy number 5–11 (broad region; genes not listed).
- chr12:65,278,643–65,491,430, 1 gene, copy number 10 (within-gene range 3–10): MSRB3.
- chr12:65,418,731–65,663,299, 5 genes, copy number 10 (within-gene range 3–10): KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2.
- chr12:65,824,460–67,069,162, 22 genes, copy number 9–12 (within-gene range 3–12): HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:68,674,371–71,586,310, 56 genes, copy number 24–44 (within-gene range 2–44): AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1.
- chr14:22,155,079–22,486,296, 39 genes, copy number 5: TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr20:62,122,461–64,327,972, 132 genes, copy number 5 (broad region; genes not listed).
- chr21:44,133,610–44,210,114, 2 genes, copy number 6–16 (within-gene range 2–16): GATD3A, LINC01678.

Autosomal genes at a single copy (total copy number 1): 1,715. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
